Surgical pathology report (de-identified scan), TCGA case TCGA-06-0156, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0156-01A (Primary Tumor).

PATH.NO:4

PATHOLOGICAL DIAGNOSIS:

RIGHT OCCIPITAL LOBE BIOPSY: GLIOBLASTOMA (MIB-1: ABOUT 20%).

Operation/Specimen: Right occipital tumor - [REDACTED]

Clinical History and Pre-Op Dx: Glioblastoma right occipital.

GROSS PATHOLOGY: The specimen labeled "right occipital tumor", are multiple 0.8 to 0.6 cm. tissue fragments.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma.
Submitted in cassette 1, remaining tissue in cassette 2.
[REDACTED]

MICROSCOPIC: Sections show a high grade glioma with the following features: hypercellularity, pleomorphism, mitotic figures, vascular hyperplasia and large areas of necrosis. The MIB-1 labeling index of the tumor cells is about 20%.
[REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file bc5ba12b-1220-45be-9ec6-826736c2dc24 (TCGA-06-0156.8153DCF5-1F5C-4C26-A0CB-05E2209A62DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).